Gene-level copy-number profile of tumor specimen TCGA-2G-AAF8-01A from TCGA case TCGA-2G-AAF8, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 33.6 years (12,256 days).
Specimen TCGA-2G-AAF8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.1f5130e8-f722-46ca-b4ef-f593d8de248b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAF8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8428fe51-48d2-4ae2-9ebd-ce11d6c6e127

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 684; copy number 2: 15,037; copy number 3: 26,211; copy number 4: 12,790; copy number 5: 2,150; copy number 6: 137; copy number 7: 909; copy number 8: 170; copy number 9: 1,116; copy number 10: 351; copy number 17: 64; copy number 20: 36; copy number 33: 8; copy number 40: 146.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAF8-01A-11D-A42X-01): tumor purity 0.45, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,800 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–174,995,308, 1,116 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:12,765,849–17,910,365, 67 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:57,994,509–85,646,325, 405 genes, copy number 7 (broad region; genes not listed).
- chr12:5,531,869–32,646,050, 682 genes, copy number 7–40 (broad region; genes not listed).
- chr19:4,769,031–14,733,746, 530 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 684. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
